Somatic mutation profile of tumor specimen TCGA-2Y-A9GY-01A (aliquot TCGA-2Y-A9GY-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.2 years (23,435 days).
Specimen TCGA-2Y-A9GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c73892c8-b85e-4ed4-9ba1-919cafb58878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GY-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GY-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/933e4126-7ad9-49e5-90a8-1e48435ba6a5

The open-access MAF lists 82 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.670A>G p.R224G (on ENST00000373394 / NM_001271696.3; = p.R225G on NM_004299.6) | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV99504604; called by muse, mutect2, varscan2
- ADAMTS19 | c.1793G>T p.W598L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV99179623; called by muse, mutect2, varscan2
- ANKRD54 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99316530; called by muse, mutect2, varscan2
- ARAP3 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV53351921, COSV99500027; called by muse, mutect2, varscan2
- CD80 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99958349; called by muse, mutect2, varscan2
- CES1 | c.1094G>C p.S365T (on ENST00000361503 / NM_001025194.2; = p.S364T on NM_001266.5) | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100828747; called by muse, mutect2, varscan2
- CSMD1 | c.5407T>C p.C1803R (on ENST00000520002; = p.C1802R on NM_033225.6) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100151227; called by muse, mutect2, varscan2
- CSMD3 | c.7741A>G p.I2581V (on ENST00000297405 / NM_001363185.1; = p.I2477V on NM_052900.3) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs759390316, COSV99841376; called by muse, mutect2, varscan2
- CYP2E1 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1336298850, COSV99429136; called by muse, mutect2, varscan2
- DYSF | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 146/313 reads (47%) | catalogued as CM090599, COSV50328645, COSV50679357; called by muse, mutect2, varscan2
- FAM199X | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.348); catalogued as COSV101534168, COSV72419869; called by muse, mutect2, varscan2
- GALNT18 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99925290; called by muse, mutect2, varscan2
- GPR156 | c.2299T>G p.F767V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100251586; called by muse, mutect2, varscan2
- GPRC5C | c.445G>A p.V149M (on ENST00000652232; = p.V104M on NM_018653.4) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs751740086, COSV100702951; called by muse, mutect2, varscan2
- HOXB5 | c.71A>C p.Y24S | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99494646; called by muse, mutect2, varscan2
- IGSF9B | c.2983G>A p.V995I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs755042408, COSV100318078; called by muse, mutect2, varscan2
- JCAD | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100948505; called by muse, mutect2, varscan2
- KCNA10 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV100871459; called by muse, mutect2, varscan2
- KEAP1 | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407450, COSV99408053; called by muse, mutect2, varscan2
- MACROH2A1 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100427705; called by muse, mutect2, varscan2
- MARCHF11 | c.1175C>A p.S392* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100198122, COSV60125763; called by muse, mutect2, varscan2
- ME2 | c.1250T>C p.F417S | Missense Mutation (SNP) | VAF 107/263 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360868; called by muse, mutect2, varscan2
- MMP17 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs368162179; called by muse, mutect2, varscan2
- MYO3A | c.2873G>C p.R958P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56318875, COSV99780654; called by muse, mutect2
- NAGLU | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864279; called by muse, mutect2, varscan2
- NECAP1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.214); catalogued as rs1244038568, COSV100331621; called by muse, varscan2
- NTRK3 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.593); catalogued as rs1260748438, COSV100447528; called by muse, mutect2, varscan2
- NXNL1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100112022; called by muse, mutect2, varscan2
- OR2AG2 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.963); catalogued as rs141878691; called by muse, mutect2, varscan2
- OR5I1 | c.762A>T p.Q254H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.996); catalogued as COSV100041593; called by muse, mutect2, varscan2
- OR5W2 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100747688; called by muse, mutect2, varscan2
- OTOGL | c.5367G>C p.K1789N (on ENST00000547103; = p.K1780N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1566007022, COSV100087565; called by muse, mutect2
- OTOL1 | c.1100A>T p.Y367F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs570932275, COSV60009147; called by muse, mutect2, varscan2
- PAH | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as CM135059, COSV100188272; called by muse, mutect2, varscan2
- PDCD7 | c.1009+1G>T p.X337_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99200151; called by muse, mutect2, varscan2
- PRSS8 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99571664; called by muse, mutect2, varscan2
- PTP4A1 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV101037879; called by muse, mutect2
- R3HDML | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53836950, COSV99407230; called by muse, mutect2, varscan2
- RPS6KA3 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101084548; called by muse, mutect2, varscan2
- SIM1 | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53495852, COSV99492578; called by muse, mutect2, varscan2
- SRRM2 | c.3623C>G p.T1208S | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100071167; called by muse, mutect2, varscan2
- STAT4 | c.53T>A p.V18E | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100636120; called by muse, mutect2, varscan2
- STOML3 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101105356, COSV65510756; called by muse, mutect2, varscan2
- SUPT6H | c.2977G>T p.G993* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100112601; called by muse, mutect2, varscan2
- SVEP1 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs778809311, COSV100238601; called by muse, mutect2, varscan2
- TEX14 | c.2716A>G p.T906A (on ENST00000240361 / NM_001201457.2; = p.T900A on NM_031272.5) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs369322235, COSV99542921; called by muse, mutect2, varscan2
- TIGD5 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100364122; called by muse, mutect2, varscan2
- TMED1 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV99284225; called by muse, mutect2, varscan2
- TNFRSF21 | c.1784A>G p.D595G | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99729988; called by muse, mutect2, varscan2
- TOB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99278902; called by muse, mutect2, varscan2
- WDR4 | c.976-1G>T p.X326_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100375329, COSV100375332; called by muse, mutect2, varscan2
- ZC3H12C | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs767673614, COSV99585180; called by muse, mutect2, varscan2
- FAM83H | c.1324del p.R442Afs*103 | Frame Shift Del (DEL) | VAF 281/1279 reads (22%) | called by mutect2, pindel, varscan2
- NADK | c.676_677insGAAA p.Q226Rfs*37 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | called by mutect2, pindel*, varscan2
- SP140 | c.994_997delinsA p.S332_E333delinsK | In Frame Del (DEL) | VAF 27/130 reads (21%) | called by pindel, varscan2*
- TTC27 | c.2359del p.M787Cfs*32 | Frame Shift Del (DEL) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- CCDC24 | c.120G>A p.R40= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV100530865; called by muse, mutect2, varscan2
- CCT7 | c.1593A>T p.T531= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as COSV99241006; called by muse, mutect2, varscan2
- CD5L | c.885C>T p.F295= | Silent (SNP) | VAF 79/160 reads (49%) | catalogued as COSV100941098; called by muse, mutect2, varscan2
- CHD4 | c.5470C>T p.L1824= (on ENST00000357008 / NM_001363606.2; = p.L1835= on NM_001273.5) | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs778830438, COSV100445076; called by muse, mutect2, varscan2
- CYTIP | c.1047T>C p.H349= | Silent (SNP) | VAF 216/454 reads (48%) | catalogued as COSV99938827; called by muse, mutect2, varscan2
- DENND4A | c.1260C>T p.I420= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV101475336; called by muse, mutect2, varscan2
- DNAAF1 | c.1272G>A p.S424= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs772170131, COSV57576413; called by muse, mutect2, varscan2
- EPB41 | c.111A>G p.E37= | Silent (SNP) | VAF 128/453 reads (28%) | catalogued as COSV100549108; called by muse, mutect2, varscan2
- GRIK2 | c.2691C>T p.N897= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs761836841, COSV100027751; called by muse, mutect2, varscan2
- HFM1 | c.1587C>A p.P529= | Silent (SNP) | VAF 54/282 reads (19%) | catalogued as COSV99646382; called by muse, mutect2, varscan2
- MORC1 | c.321C>T p.S107= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV51724236; called by muse, mutect2, varscan2
- NGEF | c.858G>A p.A286= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs527494178, COSV99887773; called by muse, mutect2, varscan2
- PER2 | c.2703G>A p.A901= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs575531966, COSV99612287; called by muse, mutect2
- RYR3 | c.12037C>T p.L4013= (on ENST00000389232; = p.L4014= on NM_001036.6) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV101213299; called by muse, mutect2, varscan2
- SFXN3 | c.852C>T p.P284= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV99827541; called by muse, mutect2, varscan2
- SLC35D2 | c.459C>T p.A153= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV99480945; called by muse, mutect2, varscan2
- SYT16 | c.1525C>T p.L509= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV101413661; called by muse, mutect2, varscan2
- TDRD6 | c.1371A>G p.P457= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs769106093, COSV100287972; called by muse, mutect2, varscan2
- THSD7B | c.2634C>G p.S878= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV99755053; called by muse, mutect2, varscan2
- TRPM5 | c.780C>T p.A260= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs772192123, COSV99330351; called by muse, mutect2, varscan2
- VPS54 | c.675T>G p.S225= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as COSV99708472; called by muse, mutect2, varscan2
- ACSL6 | c.993+77G>C | Intron (SNP) | VAF 113/228 reads (50%) | catalogued as COSV99734292; called by muse, mutect2, varscan2
- DCX | c.-22-458C>A | Intron (SNP) | VAF 176/461 reads (38%) | catalogued as COSV100576134; called by muse, mutect2, varscan2
- MIR890 | n.61G>A | RNA (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- NRXN3 | c.602-5451C>T | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99820522; called by muse, mutect2, varscan2
